Somatic mutation profile of tumor specimen TCGA-BD-A3EP-01A (aliquot TCGA-BD-A3EP-01A-11D-A22F-10) from TCGA case TCGA-BD-A3EP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 76.0 years (27,756 days).
Specimen TCGA-BD-A3EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8219d6d-29e6-4108-99f8-7075ee40e440.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BD-A3EP-11A (Solid Tissue Normal), aliquot TCGA-BD-A3EP-11A-12D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f15a5c3-ef16-491a-b5cc-5474dd799fee

The open-access MAF lists 102 somatic variants for this specimen: 86 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 71, Silent 16, Frame Shift Del 5, Nonsense Mutation 5, Splice Site 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA10 | c.2291T>A p.F764Y | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52218149; called by muse, mutect2, varscan2
- ACAD11 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs542883164, COSV53893505; called by muse, mutect2, varscan2
- ADAMTS6 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV66856697; called by muse, mutect2, varscan2
- AMPD3 | c.515G>T p.R172L (on ENST00000396553 / NM_001025389.2; = p.R181L on NM_000480.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV101158088, COSV67329860; called by muse, mutect2, varscan2
- AQP5 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV53310618; called by muse, mutect2, varscan2
- ARID1B | c.4358C>A p.A1453E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV51648460; called by muse, mutect2, varscan2
- ATAD2B | c.3952C>A p.P1318T | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53195069; called by muse, mutect2, varscan2
- ATP11B | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs778203393, COSV60026046; called by muse, mutect2, varscan2
- BMP5 | c.844A>G p.N282D | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.595); catalogued as COSV63700913; called by muse, mutect2, varscan2
- BTBD6 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV59265856, COSV59266936; called by muse, mutect2, varscan2
- CASR | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.525); catalogued as COSV56134155; called by muse, mutect2
- CELSR1 | c.5507G>T p.G1836V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV53083415; called by muse, mutect2, varscan2
- CLEC18B | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.206); catalogued as COSV60576469; called by muse, mutect2, varscan2
- CNTLN | c.2660T>C p.I887T | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs369583267; called by muse, mutect2
- COL4A4 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV61629482; called by muse, mutect2, varscan2
- CPNE4 | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV70189908; called by muse, mutect2, varscan2
- CPSF1 | c.15C>A p.Y5* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV52777578; called by muse, mutect2, varscan2
- CRISPLD1 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV51544188; called by muse, mutect2, varscan2
- DDX56 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV51835431; called by muse, mutect2, varscan2
- DEFB113 | c.67A>T p.K23* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as COSV59037108, COSV59038044; called by muse, mutect2, varscan2
- DEFB128 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 101/442 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV57685385, COSV57685654; called by muse, mutect2, varscan2
- DICER1 | c.5623G>A p.D1875N | Missense Mutation (SNP) | VAF 113/311 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs745601023, COSV58615623, COSV58630907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK5 | c.650A>C p.E217A | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52816456; called by muse, mutect2, varscan2
- ERCC4 | c.2251T>C p.Y751H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.307); catalogued as COSV61310620; called by muse, mutect2, varscan2
- FAIM2 | c.801+2T>A p.X267_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57737825; called by muse, mutect2, varscan2
- FCAMR | c.1507A>G p.M503V (on ENST00000324852 / NM_001170631.2; = p.P235= on NM_032029.4) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61366670; called by muse, mutect2, varscan2
- GABRQ | c.344A>C p.K115T | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64780821; called by muse, mutect2, varscan2
- GFM2 | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 94/406 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57189623; called by muse, mutect2, varscan2
- H4C12 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV62743680; called by muse, mutect2, varscan2
- HRG | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs781333544, COSV51643977; called by muse, mutect2, varscan2
- HYDIN | c.12812C>T p.A4271V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as COSV101124974; called by muse, mutect2, varscan2
- IGDCC3 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs372129215; called by muse, mutect2
- IKBKB | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60595751; called by muse, mutect2, varscan2
- ITGA7 | c.2174G>A p.G725E (on ENST00000555728; = p.G681E on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.329); catalogued as rs1387208599, COSV57691578; called by muse, mutect2
- JAK1 | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61087101; called by muse, mutect2, varscan2
- KCNK9 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57278021; called by muse, mutect2, varscan2
- KDM2A | c.571A>T p.M191L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV67081009; called by muse, mutect2, varscan2
- KRT86 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as COSV53291421; called by muse, mutect2, varscan2
- LCE1E | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100908554, COSV64219502; called by muse, mutect2, varscan2
- LOXL4 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375427147; called by muse, mutect2
- LRP1 | c.5990C>T p.S1997F | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54501960; called by muse, mutect2, varscan2
- LRRC46 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV51634875, COSV99274284; called by muse, mutect2
- MED7 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99644213; called by muse, mutect2
- MORC1 | c.1990G>T p.V664F | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV51713824; called by muse, mutect2, varscan2
- MSRB2 | c.176C>G p.T59S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV64737097; called by muse, mutect2, varscan2
- MTCL1 | c.3679G>C p.V1227L (on ENST00000306329 / NM_001378206.1; = p.V908L on NM_015210.4) | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV60403153; called by muse, mutect2
- MXRA5 | c.2295T>A p.F765L | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54223617; called by muse, mutect2, varscan2
- NXPE3 | c.1522A>G p.I508V | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200530322, COSV56288781; called by muse, mutect2, varscan2
- OPCML | c.361A>T p.N121Y | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV59403948; called by muse, mutect2, varscan2
- OR51G2 | c.656T>G p.I219S | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991774; called by muse, mutect2, varscan2
- OR51I1 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV66507211, COSV66508434; called by muse, mutect2, varscan2
- OR6B3 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60112632; called by muse, mutect2, varscan2
- PEG3 | c.480C>T p.F160= | Splice Region (SNP) | VAF 14/66 reads (21%) | catalogued as COSV55624508; called by muse, mutect2, varscan2
- PIK3R2 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs868385898, COSV53217390; called by muse, mutect2, varscan2
- PKP4 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 47/254 reads (19%) | catalogued as COSV67675566; called by muse, mutect2, varscan2
- PPP2R3C | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54831284; called by muse, mutect2, varscan2
- RAPGEF6 | c.4483C>T p.P1495S | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV99725740; called by muse, mutect2
- SASH1 | c.1244A>G p.N415S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1363377316, COSV66558830; called by muse, mutect2, varscan2
- SETX | c.2873T>C p.I958T | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV56378792; called by muse, mutect2, varscan2
- SLBP | c.429C>G p.N143K | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs200085408, COSV59183533; called by muse, mutect2, varscan2
- SLC50A1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.28); catalogued as COSV57596208; called by muse, mutect2, varscan2
- SLC9C2 | c.3143T>G p.I1048S | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV62943766; called by muse, mutect2, varscan2
- SNRK | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56065947; called by muse, mutect2, varscan2
- SP4 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs767714920, COSV56020739; called by muse, mutect2, varscan2
- SULT1A2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs777311279, COSV57680709; called by muse, mutect2, varscan2
- TAF1 | c.2204A>G p.H735R (on ENST00000373790 / NM_138923.4; = p.H756R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52107358; called by muse, mutect2, varscan2
- TASOR | c.1769C>T p.S590L (on ENST00000355628 / NM_001365636.2; = p.S194L on NM_015224.3) | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as rs771218781, COSV62926747; called by muse, mutect2, varscan2
- TBCD | c.3095A>G p.D1032G | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV62797555; called by muse, mutect2, varscan2
- TEK | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV66227378; called by muse, mutect2, varscan2
- TEX15 | c.5149C>T p.R1717* (on ENST00000256246; = p.R2100* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as rs1324219823, COSV56341451; called by muse, mutect2, varscan2
- TMC3 | c.2906C>A p.A969D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV63922176; called by muse, mutect2, varscan2
- TMEM87A | c.308T>G p.L103W | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1276332156, COSV56197291; called by muse, mutect2, varscan2
- USP4 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55534882; called by muse, mutect2, varscan2
- VPS13B | c.8256A>C p.Q2752H | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62133039; called by muse, mutect2, varscan2
- WDHD1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 122/295 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1355551036, COSV62212829; called by muse, mutect2, varscan2
- ZNF429 | c.1619A>T p.E540V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV61914409; called by muse, mutect2, varscan2
- BIRC6 | c.724del p.I242* | Frame Shift Del (DEL) | VAF 30/171 reads (18%) | called by mutect2, pindel, varscan2
- CUL1 | c.511_514del p.L171Sfs*4 | Frame Shift Del (DEL) | VAF 30/166 reads (18%) | called by pindel, varscan2
- GPR132 | c.788_789insA p.V264Rfs*41 | Frame Shift Ins (INS) | VAF 37/179 reads (21%) | called by mutect2, pindel*, varscan2
- GRAMD1B | c.2053del p.Q685Nfs*20 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- HSPG2 | c.10984_10997del p.V3662Hfs*109 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- IGLJ3 | c.142A>C p.T48P | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- ODF2 | c.1835_1838del p.E612Afs*50 (on ENST00000434106 / NM_153433.2; = p.E588Afs*50 on NM_002540.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | called by mutect2, pindel, varscan2
- OFCC1 | n.62-2A>G | Splice Site (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- SCFD1 | c.328_332dup p.E112Yfs*7 | Frame Shift Ins (INS) | VAF 48/195 reads (25%) | called by pindel, varscan2
- CACNA1S | c.2868G>A p.R956= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- CACNB1 | c.699C>A p.I233= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV59998001, COSV59999026; called by muse, mutect2, varscan2
- CSN3 | c.471T>C p.T157= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV59243425; called by muse, mutect2
- FAT3 | c.12873C>A p.A4291= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV53074912; called by muse, mutect2, varscan2
- FATE1 | c.51A>G p.A17= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV64848832; called by muse, mutect2, varscan2
- GLA | c.294C>A p.P98= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV54508094; called by muse, mutect2, varscan2
- IL1F10 | c.84G>T p.L28= | Silent (SNP) | VAF 11/138 reads (8%) | catalogued as rs199770962, COSV61750277; called by muse, mutect2
- KIRREL1 | c.1371C>T p.T457= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV63285267; called by muse, mutect2, varscan2
- LTV1 | c.1371A>G p.R457= | Silent (SNP) | VAF 72/250 reads (29%) | catalogued as COSV52785451; called by muse, mutect2, varscan2
- MICAL3 | c.5397C>G p.L1799= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV71588042; called by muse, mutect2, varscan2
- MYCBPAP | c.2097C>T p.S699= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs1464601611, COSV60405402; called by muse, mutect2, varscan2
- NCAM1 | c.1032T>A p.S344= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV57510474; called by muse, mutect2
- OPLAH | c.1509G>A p.L503= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV70677030; called by muse, mutect2, varscan2
- PCLO | c.15282T>C p.S5094= | Silent (SNP) | VAF 106/481 reads (22%) | catalogued as COSV61615696; called by muse, mutect2, varscan2
- PDIA5 | c.894C>A p.V298= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV60247073; called by muse, mutect2, varscan2
- WDCP | c.516G>A p.V172= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs1228513321, COSV54591469; called by muse, mutect2, varscan2
